CCDI case PBCFRE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/924c0f26-e525-404b-a23b-a7003972fcc0

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.5 years (3,471 days).

Biospecimens (3 samples)
- Sample 0DR3LV: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRKKJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DRKKS: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
